Surgical pathology report (de-identified scan), TCGA case TCGA-GC-A3BM, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-GC-A3BM-01A (Primary Tumor).

[page 1 of 3]
Sex: Male
D.O.B.:
MRN #:
Ref Phy...

(Age:)

PHYSICIAN INFORMATION

SPECIMEN INFO

Collected:
Received:
Reported: 1

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Serosal implant:
Metastatic high-grade urothelial carcinoma.
- B. Right ureter distal margin:
Benign, no pathological diagnosis.
- C. Left ureter distal margin:
Benign, no pathological diagnosis.
- D. Cystectomy and prostatectomy:
Carcinoma of bladder and additional incidental carcinoma of prostate.
- Cystectomy: Carcinoma.

Tumor Characteristics:

1. Histologic type: Urothelial.
2. Histologic grade: High-grade (grade III).
3. Tumor size: Largest representing dome of bladder approximately 1.5 x 1.0 x 0.8 cm.
4. Microscopic tumor extension: Tumor invades deep muscularis propria (outer half).
5. Lymphovascular space invasion Present.

Surgical Margins:

1. Margins uninvolved.
- Other:
1. Associated epithelial lesions: Urothelial carcinoma in situ.
2. Other significant findings: Metastatic urothelial carcinoma is identified in specimen A as a serosal implant.
3. pTNM stage: pT2b,N0.

Prostatectomy: Carcinoma.

Tumor Characteristics:

1. Histologic type: Adenocarcinoma, conventional type.
2. Prostate size: 5.0 x 4.0 x 3.5 cm.
3. Tumor quantitation: Approximately 5% of gland volume.
4. Gleason grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 3/5.
- c. Total Gleason score: 6/10.

5. Extraprostatic extension: No.
6. Seminal vesicle involvement: No.
7. Lymphovascular space invasion: Not identified.
8. High grade PIN: Present.
9. Treatment effect: None identified.

Surgical Margin Status:

1. Margins uninvolved.

Lymph Node Status (utilizing specimens E and F):

1. Total number of lymph nodes received: 2.
2. Total number of lymph nodes containing metastatic carcinoma: None (0/2).
- Other:
1. Other significant findings: Benign prostatic hyperplasia.
2. pTNM stage: pT2c,N0.

- E. Right pelvic lymph node:
Benign, hyperplasia (0/1).

ICD-0-3

carcinoma, urothelial, NOS 8120/3

Site: bladder, dome C67.1

10/26/11 hu

[page 2 of 3]
DIAGNOSIS

- F. Left pelvic lymph node:
Benign, hyperplasia (0/1).
- G. Vermiform appendix
No pathological diagnosis.

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Bladder CA

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Serosal implant
B. Right ureter, clip on distal margin
C. Distal left ureter
D. Bladder, prostate
E. Right pelvic lymph node
F. Left pelvic lymph node
G. Appendix

SPECIMEN DATA

GROSS DESCRIPTION:

A. The first container A is labeled _____, serosal implant. The specimen consists of a gray tan nodule measuring 2.0 x 1.5 x 1.0 cm. The nodule is bisected. A portion was examined at the time of surgery. The nodule is entirely submitted in cassettes _____ as follows: frozen section—1; remainder of nodule—2.

B. The second container B is labeled _____, right ureter, clip is on distal margin. The specimen consists of a portion of ureter measuring 0.7 cm in diameter and 0.2 cm in length. The specimen was examined at the time of surgery and is subsequently entirely submitted in a single cassette.

C. The third container C is labeled _____, distal left ureter. The specimen consists of a portion of ureter measuring 0.8 cm in diameter and 0.2 cm in length. The specimen was examined at the time of surgery and is subsequently entirely submitted in a single cassette.

D. The fourth container D is labeled _____, bladder, prostate. The specimen consists of a bladder, prostate and attached perivesicular fat measuring in total 14.0 x 10.0 x 7.0 cm and weighs 278 grams. The bladder itself measures 8.5 x 6.0 x 4.5 cm. The bladder has been received bisected into anterior and posterior. The mucosal surface is light tan to gray tan edematous. There are multiple foci of brown tan nodules involving the dome, right and left lateral walls measuring from 0.5 to 1.5 cm. On the left lateral wall there is an area of ulceration measuring 1.0 x 0.5 cm. The most distal nodule is within 3.2 cm of the distal resection margin at the prostatic urethra. The right and left ureters are probed and are patent and are grossly uninvolved by the mass. The left ureter is dilated up to 0.7 cm. The most distal lesion appears to be right above the trigone. On sectioning the lesions appear to extend superficially into underlying wall and is 1.5 cm from the inked deep margin. The prostate measures 5.0 x 4.0 x 3.5 cm. The cut surface has a gray tan nodular architecture. A lesion is not identified grossly. The left and right seminal vesicle and vas deferens are identified and appear grossly unremarkable. On sectioning through the perivesicular fat there are no lymph nodes grossly identified. Received with the specimen are three cassettes, one green, one yellow, one blue, labeled _____. Representative sections are submitted in cassettes _____ as follows: perpendicular sections taken from the distal margin at the prostatic urethra—1 and 2; sections from the lesions involving the dome—3; right lateral wall—4; left lateral wall—5; sections from the large lesion involving the trigone—6 to 8; floor of bladder—9; right distal ureter—10; right proximal ureter taken at the orifice—11; left distal ureter—12; left proximal ureter taken at the orifice—13; left lobe of prostate—14; right seminal vesicle and vas—15; right lobe of prostate—16; left seminal vesicle and vas—17.

E. The fifth container E is labeled _____, right pelvic lymph node. The specimen consists of a portion of fibroadipose tissue measuring 3.0 x 3.5 x 1.0 cm. Sectioning reveals a single lymph node measuring 2.5 x 1.4 x 1.7 cm, bisected, examined at the time of surgery and the frozen section is subsequently entirely submitted in a single cassette.

F. The sixth container F is labeled _____, left pelvic lymph node. The specimen consists of a portion of fibroadipose tissue measuring 4.0 x 3.0 x 1.0 cm. Sectioning reveals a single lymph node measuring 1.0 x 1.0 x 0.6 cm. The lymph node was sectioned, examined at the time of surgery and the frozen section is subsequently entirely submitted in a single cassette.

G. The seventh container G is labeled _____, appendix. The specimen consists of an appendix measuring 6.0 cm in length and 0.5 cm in

[page 3 of 3]
diameter with attached periappendiceal fat measuring 2.0 cm in thickness that is yellow to brown tan with slight hemorrhage. The surface of the appendix is gray to brown tan. There is no evidence of perforation grossly identified. On sectioning there is a small amount of yellow tan material within the lumen. There are no fecaliths or lesions identified grossly. Representative sections are submitted in cassettes.

On part D, additional sections from the prostate from the right lobe are submitted in blocks 18-20 and left lobe in blocks 21-23.

Source: NCI Genomic Data Commons file 5fad66b7-2bc3-4030-ac18-9cc9503f94fc (TCGA-GC-A3BM.F3408556-9259-4700-B9A0-F41E516B420C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).